TCGA case TCGA-QQ-A5V2 — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Fibromatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c030f196-9591-4b0e-ad72-2320f277773b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 42 years; Vital status: Alive.

Diagnoses (1)
1. Malignant fibrous histiocytoma: ICD-O-3 morphology code: 8830/3; ICD-10 code: C49.5; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of pelvis; Classification of tumor: primary; Age at diagnosis: 42.2 years (15,420 days); Year of diagnosis: 2006; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: No; Necrosis present: No; Tumor depth descriptor: Superficial.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 4.5; Tumor length measurement: 11; Tumor width measurement: 10.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 56.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-QQ-A5V2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 180 mg.
  Slide TCGA-QQ-A5V2-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-QQ-A5V2-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-QQ-A5V2-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No.
- Primary pathology: Histologic diagnosis: Giant cell 'MFH' / Undifferentiated pleomorphic sarcoma with giant cells; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Disease multifocal indicator: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower abdominal/Pelvic - Pelvic.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome at TCGA followup: Complete Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 56 days; disease-specific survival: no event (censored), 56 days; progression-free interval: no event (censored), 56 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-QQ-A5V2-01A-11D-A32H-01): tumor purity 0.4, ploidy 2, whole-genome doublings 0.
